Somatic mutation profile of tumor specimen TCGA-AF-6655-01A (aliquot TCGA-AF-6655-01A-11D-1826-10) from TCGA case TCGA-AF-6655, project TCGA-READ (Rectum Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectosigmoid junction; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 66.9 years (24,417 days).
Specimen TCGA-AF-6655-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f4bce00b-a5fa-4c8f-a225-03ea0b904344.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AF-6655-10A (Blood Derived Normal), aliquot TCGA-AF-6655-10A-01D-1826-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bca95627-303b-4327-82a6-36e38172ecdb

The open-access MAF lists 73 somatic variants for this specimen: 59 protein-altering or splice-affecting, 13 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 50, Silent 13, Frame Shift Del 5, Nonsense Mutation 2, In Frame Del 1, Intron 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 48/136 reads (35%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.44); catalogued as rs112445441, CM125166, COSV55497357, COSV55497388, COSV55522580; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.613T>G p.Y205D | Missense Mutation (SNP) | VAF 20/58 reads (34%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1057520008, CD100447, COSV52760580, COSV52806341, COSV52877975, COSV52979708; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- ABLIM3 | c.1601G>A p.R534Q | Missense Mutation (SNP) | VAF 15/26 reads (58%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.9); catalogued as rs373620710, COSV100448778, COSV58644797; called by muse, mutect2, varscan2
- ADCY1 | c.1234C>T p.R412C | Missense Mutation (SNP) | VAF 36/142 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.415); catalogued as rs536487311, COSV52032873; called by muse, mutect2, varscan2
- APC | c.4335del p.A1446Lfs*27 | Frame Shift Del (DEL) | VAF 18/125 reads (14%) | catalogued as COSV57331309; called by mutect2, pindel, varscan2
- ATG9B | c.2152T>G p.W718G | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99871455; called by muse, mutect2, varscan2
- C18orf54 | c.263A>G p.Y88C | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as rs564302523, COSV55618435; called by muse, mutect2, varscan2
- CACNA1E | c.4745G>A p.R1582H | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV62393577; called by muse, mutect2, varscan2
- CCBE1 | c.193G>A p.E65K | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT tolerated (0.15); PolyPhen benign (0.168); catalogued as rs984126526, COSV71671256; called by muse, mutect2, varscan2
- CCDC136 | c.2752G>A p.D918N | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.829); catalogued as rs540834725, COSV52800821, COSV52801658; called by muse, mutect2, varscan2
- CCDC178 | c.650T>C p.V217A | Missense Mutation (SNP) | VAF 29/92 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs776170513, COSV55778923, COSV55802266; called by muse, mutect2, varscan2
- CDH19 | c.2267G>A p.R756H | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0.015); catalogued as COSV100050605; called by muse, mutect2, varscan2
- CDH8 | c.2206C>T p.P736S | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.994); catalogued as COSV54875128; called by muse, mutect2, varscan2
- CDH8 | c.1495G>A p.E499K | Missense Mutation (SNP) | VAF 14/96 reads (15%) | SIFT tolerated (0.42); PolyPhen benign (0.007); catalogued as rs771617779, COSV54865437; called by muse, varscan2
- CEACAM5 | c.1742G>A p.R581H | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT tolerated (0.33); PolyPhen benign (0.01); catalogued as rs146319665; called by muse, mutect2, varscan2
- CKMT2 | c.545G>A p.R182Q | Missense Mutation (SNP) | VAF 40/73 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs368812686; called by muse, mutect2, varscan2
- CNPY2 | c.227C>T p.A76V | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated (0.27); PolyPhen benign (0.039); catalogued as COSV56264542; called by muse, mutect2, varscan2
- CPEB2 | c.3002G>A p.R1001H | Missense Mutation (SNP) | VAF 25/81 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.741); catalogued as rs759238935, COSV52592629; called by muse, mutect2, varscan2
- FAT3 | c.10238C>T p.S3413F | Missense Mutation (SNP) | VAF 33/140 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53127459; called by muse, mutect2, varscan2
- FBXO40 | c.1135G>T p.D379Y | Missense Mutation (SNP) | VAF 44/87 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57524889; called by muse, mutect2, varscan2
- FLRT2 | c.1649C>T p.A550V | Missense Mutation (SNP) | VAF 16/93 reads (17%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.638); catalogued as rs201981148, COSV58140190; called by muse, mutect2, varscan2
- FSHR | c.1193G>T p.R398M | Missense Mutation (SNP) | VAF 15/142 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV58626179; called by muse, mutect2, varscan2
- GPR37 | c.1315G>A p.D439N | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.183); catalogued as rs757152085, COSV58256852; called by muse, mutect2, varscan2
- GRIP1 | c.2815C>G p.H939D (on ENST00000359742 / NM_001379345.1; = p.H887D on NM_021150.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT tolerated (0.48); PolyPhen benign (0.177); catalogued as COSV54028381; called by muse, varscan2
- KATNAL1 | c.121C>T p.Q41* | Nonsense Mutation (SNP) | VAF 25/141 reads (18%) | catalogued as COSV66063681; called by muse, mutect2, varscan2
- LIPE | c.2261C>T p.P754L | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1248472812, COSV54923518; called by muse, mutect2, varscan2
- MASP2 | c.1240G>A p.A414T | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.485); catalogued as COSV68896875; called by muse, mutect2
- MROH2B | c.3559C>T p.R1187W | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.989); catalogued as rs369303264; called by muse, mutect2, varscan2
- NLRX1 | c.1003G>A p.V335I | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT tolerated (0.21); PolyPhen benign (0.006); catalogued as rs778713378, COSV52705944; called by muse, mutect2, varscan2
- OBSL1 | c.1112C>T p.T371M | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs777770619, COSV99216596, COSV99217398; called by muse, mutect2, varscan2
- OPN5 | c.572A>G p.Q191R | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT tolerated (0.3); PolyPhen benign (0.376); catalogued as COSV99789792; called by muse, mutect2, varscan2
- OR2T6 | c.416G>A p.R139Q | Missense Mutation (SNP) | VAF 39/127 reads (31%) | SIFT tolerated (0.22); PolyPhen benign (0.168); catalogued as rs376407108; called by muse, mutect2, varscan2
- PIPOX | c.554C>T p.T185M | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT tolerated (0.05); PolyPhen benign (0.22); catalogued as rs777572438, COSV60142333; called by muse, mutect2, varscan2
- PLEKHG4B | c.3313C>T p.R1105W (on ENST00000283426; = p.R1461W on NM_052909.5) | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.677); catalogued as rs759623099, COSV52049323; called by muse, mutect2, varscan2
- PPFIA4 | c.2141G>A p.G714D (on ENST00000447715; = p.G715D on NM_001304331.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT deleterious (0.03); PolyPhen benign (0.147); catalogued as COSV55316770, COSV55319689; called by muse, varscan2
- PPP4R3A | c.887A>G p.N296S | Missense Mutation (SNP) | VAF 32/92 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.812); catalogued as COSV61505290; called by muse, mutect2, varscan2
- PRSS1 | c.442G>T p.A148S | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as COSV61193878; called by muse, mutect2, varscan2
- RAB6B | c.115G>A p.D39N | Missense Mutation (SNP) | VAF 37/73 reads (51%) | SIFT deleterious (0.01); PolyPhen benign (0.124); catalogued as COSV53314281; called by muse, mutect2, varscan2
- RSPH14 | c.656T>C p.I219T | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT tolerated (0.25); PolyPhen benign (0.038); catalogued as COSV99320603; called by muse, mutect2, varscan2
- SCGB1D2 | c.55+1del | Frame Shift Del (DEL) | VAF 17/60 reads (28%) | catalogued as COSV99793585; called by mutect2, pindel, varscan2
- SPAG7 | c.328-5_328-3del | Splice Region (DEL) | VAF 11/30 reads (37%) | catalogued as rs780734126; called by pindel, varscan2
- SULF2 | c.1832T>C p.V611A | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV63417231; called by muse, mutect2, varscan2
- TCF7L2 | c.70G>T p.E24* | Nonsense Mutation (SNP) | VAF 22/86 reads (26%) | catalogued as COSV60506950, COSV60507589; called by muse, mutect2, varscan2
- TIGD5 | c.1209C>G p.F403L | Missense Mutation (SNP) | VAF 20/28 reads (71%) | SIFT deleterious (0.01); PolyPhen benign (0.203); catalogued as COSV55307472; called by muse, mutect2, varscan2
- TRIM42 | c.649C>T p.R217C | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as COSV53880850, COSV99648250; called by muse, mutect2, varscan2
- TTN | c.67577G>T p.R22526I (on ENST00000591111; = p.R15102I on NM_003319.4) | Missense Mutation (SNP) | VAF 49/90 reads (54%) | PolyPhen possibly damaging (0.839); catalogued as COSV60136852, COSV60332025; called by muse, mutect2, varscan2
- UBE2K | c.248A>G p.N83S | Missense Mutation (SNP) | VAF 23/70 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54690955; called by muse, mutect2, varscan2
- USP21 | c.481G>A p.G161R | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.175); catalogued as COSV57089264, COSV57089431; called by muse, mutect2, varscan2
- VCAN | c.3682G>A p.A1228T | Missense Mutation (SNP) | VAF 75/151 reads (50%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs772576325, COSV99425315; called by muse, mutect2, varscan2
- WDR33 | c.2164C>T p.P722S | Missense Mutation (SNP) | VAF 7/10 reads (70%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.324); catalogued as COSV59250683; called by muse, mutect2, varscan2
- ZDHHC5 | c.1130G>A p.R377H | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT tolerated (0.57); PolyPhen possibly damaging (0.695); catalogued as rs755434833, COSV54707400; called by muse, mutect2, varscan2
- ZNF334 | c.1628C>A p.P543Q | Missense Mutation (SNP) | VAF 37/201 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.805); catalogued as COSV61619041; called by muse, mutect2, varscan2
- ZNF7 | c.1871G>A p.R624H | Missense Mutation (SNP) | VAF 49/97 reads (51%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs757438179, COSV57384129; called by muse, mutect2, varscan2
- ACACA | c.1822A>G p.I608V | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT tolerated (0.22); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- APC | c.1275del p.A426Lfs*28 | Frame Shift Del (DEL) | VAF 76/195 reads (39%) | called by mutect2, pindel, varscan2
- ARHGEF11 | c.913_915del p.N305del | In Frame Del (DEL) | VAF 28/78 reads (36%) | called by pindel, varscan2
- CYP7A1 | c.918del p.A307Qfs*2 | Frame Shift Del (DEL) | VAF 52/149 reads (35%) | called by mutect2, pindel, varscan2
- KIN | c.1095_1096del p.A367Yfs*5 | Frame Shift Del (DEL) | VAF 13/44 reads (30%) | called by mutect2, pindel, varscan2
- MTMR1 | c.814A>G p.K272E | Missense Mutation (SNP) | VAF 6/112 reads (5%) | SIFT tolerated (0.47); PolyPhen benign (0.103); called by muse, mutect2
- CSMD1 | c.8607C>T p.A2869= (on ENST00000520002; = p.A2868= on NM_033225.6) | Silent (SNP) | VAF 6/15 reads (40%) | catalogued as rs779219870, COSV59338330; called by muse, mutect2, varscan2
- DEUP1 | c.1578G>A p.S526= | Silent (SNP) | VAF 71/216 reads (33%) | catalogued as rs780369481, COSV53211422; called by muse, mutect2, varscan2
- EXOSC10 | c.1677G>A p.P559= | Silent (SNP) | VAF 14/69 reads (20%) | catalogued as rs766343669, COSV58666017; called by muse, mutect2, varscan2
- HDAC9 | c.1740G>A p.T580= | Silent (SNP) | VAF 12/61 reads (20%) | catalogued as COSV67766560; called by muse, mutect2, varscan2
- LRRN4 | c.1551C>T p.G517= | Silent (SNP) | VAF 44/116 reads (38%) | catalogued as COSV66645768; called by muse, mutect2, varscan2
- MROH8 | c.1377C>T p.T459= | Silent (SNP) | VAF 12/107 reads (11%) | catalogued as COSV54121120; called by muse, mutect2, varscan2
- OR10AG1 | c.147C>A p.P49= | Silent (SNP) | VAF 10/146 reads (7%) | catalogued as COSV56632459, COSV56633123, COSV56634675; called by muse, mutect2
- RAB3IL1 | c.648G>A p.E216= | Silent (SNP) | VAF 11/27 reads (41%) | catalogued as rs1189385688, COSV57117910; called by muse, mutect2, varscan2
- RABGAP1L | c.1944C>T p.Y648= | Silent (SNP) | VAF 15/40 reads (38%) | catalogued as rs764187739, COSV99269202; called by muse, mutect2, varscan2
- RRAGD | c.267C>T p.N89= | Silent (SNP) | VAF 9/43 reads (21%) | catalogued as rs145002359; called by muse, mutect2, varscan2
- SLC16A13 | c.372G>A p.P124= | Silent (SNP) | VAF 7/22 reads (32%) | catalogued as rs200228263, COSV57274504; called by muse, mutect2, varscan2
- ZBTB46 | c.909G>A p.S303= | Silent (SNP) | VAF 6/43 reads (14%) | catalogued as rs1440692915, COSV55506498; called by muse, mutect2
- ZFHX4 | c.7125C>T p.N2375= | Silent (SNP) | VAF 29/53 reads (55%) | catalogued as rs1457303675, COSV51443681, COSV51476529; called by muse, mutect2, varscan2
- MMP16 | c.1222+5144G>T | Intron (SNP) | VAF 22/109 reads (20%) | catalogued as COSV99687184, COSV99687399; called by muse, mutect2, varscan2
